Somatic mutation profile of tumor specimen ALCH-B2OY-TTP1-A (aliquot ALCH-B2OY-TTP1-A-6-0-D-A777-36) from ALCHEMIST case ALCH-B2OY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.5 years (25,020 days).
Specimen ALCH-B2OY-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd22fea0-558a-4fef-9bfb-68b9d34af445.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OY-NB1-A (Blood Derived Normal), aliquot ALCH-B2OY-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25c8abd9-c8b5-4c6b-87e6-bcf82c294755

The open-access MAF lists 296 somatic variants for this specimen: 200 protein-altering or splice-affecting, 60 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 60, Intron 18, Nonsense Mutation 15, RNA 7, Splice Site 6, Frame Shift Del 6, Splice Region 5, 5'Flank 4, 5'UTR 4, 3'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4353G>A p.W1451* | Nonsense Mutation (SNP) | VAF 47/431 reads (11%) | catalogued as rs1057516404; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNC1 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554991378, COSV56393902; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 86/536 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 42/330 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 43/338 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- TWIST1 | c.309C>A p.Y103* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as rs104894054, CD033559, CM970030, CM980015, COSV99642975; ClinVar: pathogenic; called by muse, varscan2
- APOF | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs539168304, COSV58476326; called by muse, mutect2
- ARHGEF26 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 34/503 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs750625968; called by muse, mutect2
- ARID4B | c.3595G>A p.D1199N | Missense Mutation (SNP) | VAF 28/563 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV51607529; called by muse, mutect2
- CADPS | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 31/486 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs763095162; called by muse, mutect2
- CBLL1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 27/594 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV56028513; called by muse, mutect2
- CDCA3 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 48/350 reads (14%) | catalogued as rs1565523413; called by muse, mutect2, varscan2
- CDHR1 | c.558C>A p.H186Q | Missense Mutation (SNP) | VAF 98/566 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as rs934208979; called by muse, mutect2, varscan2
- CFAP99 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV72729274; called by muse, mutect2
- COL6A2 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56005397; called by muse, mutect2, varscan2
- CSMD3 | c.3584G>A p.G1195E (on ENST00000297405 / NM_001363185.1; = p.G1091E on NM_052900.3) | Missense Mutation (SNP) | VAF 60/825 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs763050358; called by muse, mutect2
- CSMD3 | c.3583G>T p.G1195W (on ENST00000297405 / NM_001363185.1; = p.G1091W on NM_052900.3) | Missense Mutation (SNP) | VAF 59/826 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52231204; called by muse, mutect2
- DCAF8 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 21/416 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV58785814; called by muse, mutect2
- DUS3L | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 56/848 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs140036183; called by muse, mutect2
- ECHDC3 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 95/417 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs201352428; called by muse, mutect2, varscan2
- FBLN2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1272556761, COSV55480844; called by muse, mutect2
- FLG | c.4504G>A p.G1502R | Missense Mutation (SNP) | VAF 54/878 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs375584758; called by muse, mutect2
- HEY2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs750183240; called by muse, mutect2, varscan2
- HFM1 | c.2632A>T p.T878S | Missense Mutation (SNP) | VAF 52/662 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as rs976430829; called by muse, mutect2
- IGKV1D-17 | c.337C>G p.H113D | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs766006052; called by muse, mutect2, varscan2
- IL36RN | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 51/451 reads (11%) | catalogued as rs771984756; called by muse, mutect2, varscan2
- ITGA4 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 20/489 reads (4%) | catalogued as COSV99276998; called by muse, mutect2
- ITPR2 | c.7624G>A p.D2542N | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258889981; called by muse, mutect2
- LPO | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51858206; called by muse, mutect2, varscan2
- MAP3K14 | c.2027C>A p.P676Q | Missense Mutation (SNP) | VAF 105/643 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV60922773; called by muse, mutect2, varscan2
- MARS1 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759552016; called by muse, mutect2
- MME | c.1957G>T p.G653* | Nonsense Mutation (SNP) | VAF 80/554 reads (14%) | catalogued as COSV64706605; called by muse, mutect2, varscan2
- MS4A6A | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 34/626 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV60619382; called by muse, mutect2
- MYH7 | c.4763G>T p.R1588L | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as CM1211645, COSV62517986; called by muse, mutect2, varscan2
- NUTM1 | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100412590; called by muse, mutect2, varscan2
- OR4D9 | c.415G>C p.G139R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV61434884; called by muse, mutect2, varscan2
- OR51E2 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.086); catalogued as COSV101211306; called by muse, mutect2
- PCDH19 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV55271650; called by muse, mutect2, varscan2
- PCDHA2 | c.2281G>T p.G761W | Missense Mutation (SNP) | VAF 64/403 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.228); catalogued as COSV65365819; called by muse, mutect2, varscan2
- PEAR1 | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV52770724; called by muse, mutect2, varscan2
- PRSS54 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV54686644; called by muse, mutect2
- PTPRT | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs888187284, COSV61993583; called by muse, mutect2
- RDH14 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs143289874; called by muse, mutect2
- RPH3AL | c.514G>C p.A172P | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.756); catalogued as COSV100047818; called by muse, mutect2
- RYR2 | c.12563T>C p.L4188P | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs1455720780, CM124708; called by muse, mutect2
- SAGE1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61012115; called by muse, mutect2, varscan2
- SCN10A | c.389C>G p.S130W | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV71861162; called by muse, mutect2
- SETD2 | c.6503C>G p.P2168R | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57440515; called by muse, mutect2
- SEZ6L | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs746898457; called by muse, mutect2, varscan2
- SIGLEC1 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV52464321; called by muse, mutect2
- SLITRK4 | c.1958A>T p.H653L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs781787181; called by muse, mutect2, varscan2
- SPATS2L | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs368871834; called by muse, mutect2
- SYNE1 | c.4838C>G p.S1613* (on ENST00000367255 / NM_182961.4; = p.S1620* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 68/765 reads (9%) | catalogued as COSV54998834; called by muse, mutect2
- TBR1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV67417934; called by muse, mutect2
- TEX13B | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs1017597061, COSV57203218; called by muse, mutect2, varscan2
- TMED9 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV60263540; called by muse, mutect2
- TMEM200A | c.641C>A p.S214* | Nonsense Mutation (SNP) | VAF 24/170 reads (14%) | catalogued as rs201963998; called by muse, mutect2, varscan2
- UNC79 | c.2212-1G>T p.X738_splice (on ENST00000393151 / NM_001346218.2; = p.X561_splice on NM_020818.5) | Splice Site (SNP) | VAF 7/136 reads (5%) | catalogued as COSV56375635; called by muse, mutect2
- VCAN | c.5464A>G p.T1822A | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1192830204; called by muse, mutect2
- ZBTB8A | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1044289980; called by muse, mutect2
- ZFAND2B | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs764885846; called by muse, mutect2, varscan2
- ZNF239 | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302439423; called by muse, mutect2
- ZNF274 | c.482G>T p.R161L (on ENST00000610905; = p.R56L on NM_016324.3) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100465481; called by muse, mutect2, varscan2
- ZNF488 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs547062492; called by muse, mutect2
- ABTB1 | c.623G>A p.C208Y (on ENST00000232744 / NM_172027.3; = p.C66Y on NM_032548.3) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ADAMTS19 | c.2278G>C p.D760H | Missense Mutation (SNP) | VAF 25/577 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- ADAMTS6 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AFAP1L1 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 40/431 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2
- ALDH4A1 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 48/203 reads (24%) | called by muse, mutect2, varscan2
- ANKRD18A | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- ANKRD36 | c.1917G>T p.M639I | Missense Mutation (SNP) | VAF 39/502 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.891); called by muse, mutect2
- APOB | c.11475C>G p.F3825L | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP4 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ARHGEF26 | c.1773T>A p.T591= | Splice Region (SNP) | VAF 31/206 reads (15%) | called by muse, mutect2, varscan2
- ASB4 | c.314_322del p.P105_K108delinsQ | In Frame Del (DEL) | VAF 47/501 reads (9%) | called by mutect2, pindel
- ATP13A5 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BICRA | c.1799A>C p.D600A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2
- BNIP2 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); called by muse, mutect2
- BTAF1 | c.4165G>T p.D1389Y | Missense Mutation (SNP) | VAF 31/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BTN1A1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); called by muse, mutect2
- C2CD2 | c.1019-3C>T | Splice Region (SNP) | VAF 28/445 reads (6%) | called by muse, mutect2
- CA2 | c.444+8G>T | Splice Region (SNP) | VAF 38/808 reads (5%) | called by muse, mutect2
- CACNA1A | c.7447T>A p.Y2483N | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CACNA1F | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.721); called by muse, mutect2
- CAMSAP2 | c.1013del p.K338Sfs*18 (on ENST00000236925 / NM_001297707.2; = p.K327Sfs*18 on NM_203459.3) | Frame Shift Del (DEL) | VAF 119/816 reads (15%) | called by mutect2, pindel, varscan2
- CARS2 | c.738G>T p.W246C | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CBARP | c.394G>T p.A132S (on ENST00000382477; = p.A138S on NM_152769.3) | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, varscan2
- CBLIF | c.1073+1G>A p.X358_splice | Splice Site (SNP) | VAF 75/573 reads (13%) | called by muse, mutect2, varscan2
- CCDC168 | c.8855C>A p.P2952Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CCDC178 | c.632A>C p.Q211P | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- CCND2 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- CDC25C | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CENPF | c.6346C>T p.Q2116* | Nonsense Mutation (SNP) | VAF 20/519 reads (4%) | called by muse, mutect2
- CEP120 | c.2507C>G p.S836C | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- CEP170B | c.1871del p.G624Afs*200 (on ENST00000453495; = p.G553Afs*200 on NM_015005.3) | Frame Shift Del (DEL) | VAF 24/157 reads (15%) | called by mutect2, pindel, varscan2
- CHMP3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2
- CIAPIN1 | c.311-2A>T p.X104_splice | Splice Site (SNP) | VAF 17/208 reads (8%) | called by muse, mutect2
- CKB | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLCN4 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 129/362 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- COG6 | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- COL17A1 | c.2152C>G p.R718G | Missense Mutation (SNP) | VAF 26/499 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL20A1 | c.3614C>T p.S1205L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- COL25A1 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 66/471 reads (14%) | called by muse, mutect2, varscan2
- COL4A4 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CPED1 | c.2761C>A p.L921M | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD1 | c.8034T>A p.A2678= (on ENST00000520002; = p.A2677= on NM_033225.6) | Splice Region (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- CTU1 | c.512A>T p.H171L | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- DCAF4L2 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 87/407 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- DNAH10 | c.6446T>A p.V2149D (on ENST00000409039; = p.V2088D on NM_207437.3) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2
- DNAH11 | c.4279A>C p.T1427P | Missense Mutation (SNP) | VAF 90/645 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- DST | c.20756G>C p.S6919T (on ENST00000361203 / NM_001374722.1; = p.S4616T on NM_015548.5) | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DST | c.9257G>T p.G3086V | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EIF2AK1 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 97/486 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- EIF4E2 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2, varscan2
- EPHA10 | c.2562+1G>T p.X854_splice | Splice Site (SNP) | VAF 73/402 reads (18%) | called by muse, mutect2, varscan2
- EPS8L3 | c.139_142delinsGAAA p.P47_E48delinsEK | Missense Mutation (ONP) | VAF 24/170 reads (14%) | called by mutect2*, pindel, varscan2*
- FAM234A | c.878A>T p.Y293F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FASLG | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.14564T>C p.I4855T | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GABRA2 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- GABRB3 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 45/492 reads (9%) | PolyPhen benign (0); called by muse, mutect2
- GALNT13 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- GATD1 | c.260A>T p.H87L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GIN1 | c.670A>C p.I224L | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); called by mutect2, varscan2
- GJA5 | c.389A>T p.K130M | Missense Mutation (SNP) | VAF 24/797 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- GNA11 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HSPG2 | c.10444G>T p.V3482F | Missense Mutation (SNP) | VAF 97/551 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- INPP5F | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRX6 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 42/359 reads (12%) | called by muse, varscan2
- ITGA4 | c.496T>A p.Y166N | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2
- ITGAD | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by mutect2, varscan2
- ITIH3 | c.1905G>C p.L635= | Splice Region (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- ITIH5 | c.473G>C p.S158T | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KBTBD7 | c.1593C>G p.I531M | Missense Mutation (SNP) | VAF 32/569 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); called by muse, mutect2
- KIAA1614 | c.2900G>C p.G967A | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.164); called by muse, mutect2
- LARS2 | c.32A>T p.Y11F | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); called by muse, mutect2
- LSM14B | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 74/432 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- MACROH2A1 | c.549C>A p.F183L (on ENST00000510038; = p.F182L on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/482 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- MARCHF10 | c.548A>T p.Q183L | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- MOB1A | c.367C>G p.Q123E | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.868); called by muse, mutect2
- MOB2 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MXRA5 | c.2674T>A p.S892T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- MYBL2 | c.2005G>T p.G669W | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO3A | c.954-2A>G p.X318_splice | Splice Site (SNP) | VAF 34/526 reads (6%) | called by muse, mutect2
- NCKAP1 | c.1423G>T p.V475F | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2
- NEGR1 | c.579T>G p.I193M | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLGN1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.038); called by muse, mutect2
- NR1H4 | c.375_387del p.A126Gfs*23 (on ENST00000551379 / NM_001206993.2; = p.A116Gfs*23 on NM_005123.4) | Frame Shift Del (DEL) | VAF 30/315 reads (10%) | called by mutect2, pindel
- NRXN2 | c.4055C>T p.T1352I | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NWD1 | c.4243T>A p.W1415R | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OMD | c.305A>C p.E102A | Missense Mutation (SNP) | VAF 33/519 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.185); called by muse, mutect2
- ONECUT3 | c.1167G>T p.Q389H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR12D3 | c.334_336delinsAT p.L112Ifs*23 | Frame Shift Del (DEL) | VAF 41/269 reads (15%) | called by pindel, varscan2*
- OR2AK2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2C3 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- OR51G1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- OR5I1 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- OSTN | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- OTOF | c.4172C>G p.S1391C (on ENST00000272371 / NM_194248.3; = p.S624C on NM_004802.4) | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2
- P2RX5 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1494C>A p.D498E (on ENST00000259318 / NM_001136562.3; = p.D729E on NM_007203.5) | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDH12 | c.2554C>A p.H852N | Missense Mutation (SNP) | VAF 30/363 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2
- PCDH8 | c.2569G>T p.A857S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCNX4 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKD1L1 | c.1898T>G p.L633R | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.132); called by muse, mutect2
- PLCB3 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 55/380 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PNLIPRP2 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PNPLA5 | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSTPIP1 | c.569T>A p.V190E | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RASSF10 | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.118); called by muse, mutect2
- RELN | c.1271T>A p.F424Y | Missense Mutation (SNP) | VAF 80/691 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RNF213 | c.11791G>C p.E3931Q | Missense Mutation (SNP) | VAF 38/688 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- SLAMF7 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.377); called by muse, mutect2
- SLC26A5 | c.1212G>C p.E404D | Missense Mutation (SNP) | VAF 53/774 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- SLC9A7 | c.1792T>A p.F598I | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, varscan2
- SMYD3 | c.415G>T p.D139Y (on ENST00000490107 / NM_001375962.1; = p.D80Y on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- SPTB | c.6612C>A p.N2204K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TADA2B | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- TANC2 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBX15 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2
- TENM2 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 36/449 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- TIAM1 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- TMEM131 | c.1587A>T p.L529F | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM225B | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- TMEM70 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 58/750 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- TRIM51 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 42/957 reads (4%) | called by muse, mutect2
- USP24 | c.532A>G p.R178G | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- WDPCP | c.1270del p.E424Rfs*21 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- XIRP2 | c.2665C>A p.L889I (on ENST00000628543; = p.L1064I on NM_152381.6) | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2
- YME1L1 | c.1583-1G>T p.X528_splice (on ENST00000326799 / NM_139312.3; = p.X471_splice on NM_014263.4) | Splice Site (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2
- ZBTB26 | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, mutect2
- ZDHHC16 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZEB1 | c.2968G>T p.A990S | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2
- ZER1 | c.943A>T p.S315C | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ZNF205 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- ZNF329 | c.642del p.N215Tfs*32 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by pindel, varscan2
- ZNF34 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF423 | c.2394C>A p.F798L (on ENST00000563137 / NM_001379286.1; = p.F790L on NM_015069.4) | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- ZNF679 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 29/426 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2
- ZZZ3 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2
- ACIN1 | c.184C>T p.L62= | Silent (SNP) | VAF 59/348 reads (17%) | catalogued as rs762808965; called by muse, mutect2, varscan2
- AKAP1 | c.813C>T p.F271= | Silent (SNP) | VAF 22/324 reads (7%) | called by muse, mutect2
- ASB5 | c.114C>A p.L38= | Silent (SNP) | VAF 34/316 reads (11%) | catalogued as COSV56670541; called by muse, mutect2, varscan2
- ATXN1L | c.1503G>T p.G501= | Silent (SNP) | VAF 34/193 reads (18%) | called by muse, mutect2, varscan2
- BDP1 | c.4839T>C p.T1613= | Silent (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2, varscan2
- C11orf86 | c.144G>A p.Q48= | Silent (SNP) | VAF 40/229 reads (17%) | catalogued as rs1159714817; called by muse, mutect2, varscan2
- CDK12 | c.168G>A p.V56= | Silent (SNP) | VAF 22/370 reads (6%) | catalogued as COSV71002174; called by muse, mutect2
- CEP170 | c.705T>C p.C235= | Silent (SNP) | VAF 69/413 reads (17%) | called by muse, mutect2, varscan2
- CMTR2 | c.219A>G p.V73= | Silent (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- COL4A1 | c.3756C>G p.P1252= | Silent (SNP) | VAF 51/666 reads (8%) | catalogued as COSV65423753; called by muse, mutect2
- CRYBA1 | c.225T>A p.G75= | Silent (SNP) | VAF 28/440 reads (6%) | called by muse, mutect2
- DEPDC5 | c.3561C>G p.A1187= (on ENST00000400246; = p.A1256= on NM_014662.5) | Silent (SNP) | VAF 14/396 reads (4%) | called by muse, mutect2
- DMXL1 | c.6390G>A p.L2130= | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as rs142411562; called by muse, mutect2, varscan2
- DNAH17 | c.1239C>G p.A413= | Silent (SNP) | VAF 30/281 reads (11%) | catalogued as rs758436054; called by muse, mutect2, varscan2
- ELF1 | c.1065C>G p.P355= | Silent (SNP) | VAF 48/628 reads (8%) | called by muse, mutect2
- FOXL1 | c.630G>T p.G210= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs944737366, COSV57213756; called by muse, mutect2
- GBX1 | c.1051C>A p.R351= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as rs202046564; called by muse, mutect2, varscan2
- GOLGB1 | c.7497A>G p.Q2499= | Silent (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- GPR15 | c.810G>T p.R270= | Silent (SNP) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- GPX8 | c.264G>T p.G88= | Silent (SNP) | VAF 41/416 reads (10%) | called by muse, mutect2
- GRM1 | c.255G>T p.T85= | Silent (SNP) | VAF 25/356 reads (7%) | catalogued as COSV99264368; called by muse, mutect2
- HOXC13 | c.321G>T p.P107= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- IGKV3-11 | c.93G>T p.L31= | Silent (SNP) | VAF 83/491 reads (17%) | catalogued as rs376010585; called by muse, mutect2, varscan2
- IPO7 | c.156G>C p.V52= | Silent (SNP) | VAF 12/308 reads (4%) | catalogued as COSV65684546; called by muse, mutect2
- KCNN1 | c.624G>A p.T208= | Silent (SNP) | VAF 19/227 reads (8%) | called by muse, mutect2
- KRT79 | c.720G>A p.K240= | Silent (SNP) | VAF 27/281 reads (10%) | called by muse, mutect2
- MEF2B | c.138C>T p.I46= | Silent (SNP) | VAF 33/561 reads (6%) | catalogued as COSV99365143; called by muse, mutect2
- MFN2 | c.1101G>A p.Q367= | Silent (SNP) | VAF 36/656 reads (5%) | catalogued as COSV52420726; called by muse, mutect2
- MMS22L | c.684G>T p.L228= | Silent (SNP) | VAF 21/201 reads (10%) | called by muse, mutect2, varscan2
- MS4A2 | c.438C>A p.T146= | Silent (SNP) | VAF 36/532 reads (7%) | called by muse, mutect2
- MUC16 | c.17478C>T p.T5826= | Silent (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- MUC4 | c.1299T>A p.T433= | Silent (SNP) | VAF 25/239 reads (10%) | called by muse, mutect2, varscan2
- NKX1-1 | c.879C>T p.S293= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- NPIPB2 | c.471G>A p.R157= (on ENST00000399147; = p.R17= on NM_001355514.1) | Silent (SNP) | VAF 30/574 reads (5%) | catalogued as rs774786918; called by muse, mutect2
- NPY1R | c.882T>A p.A294= | Silent (SNP) | VAF 39/267 reads (15%) | called by muse, mutect2, varscan2
- OOSP1 | c.294C>T p.I98= | Silent (SNP) | VAF 51/388 reads (13%) | called by muse, mutect2, varscan2
- OR10A3 | c.837G>T p.T279= | Silent (SNP) | VAF 28/465 reads (6%) | called by muse, mutect2
- OR4C16 | c.543C>A p.P181= | Silent (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- P2RY8 | c.498G>T p.P166= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as rs370702297, COSV67177127; called by muse, mutect2
- PCDHB15 | c.1554G>A p.S518= | Silent (SNP) | VAF 34/607 reads (6%) | called by muse, mutect2
- PCDHB7 | c.2157G>T p.P719= | Silent (SNP) | VAF 30/303 reads (10%) | called by muse, mutect2, varscan2
- PHACTR4 | c.1374G>T p.T458= (on ENST00000373839 / NM_001350159.2; = p.T468= on NM_023923.4) | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs769429278; called by muse, mutect2, varscan2
- POM121L2 | c.2850C>A p.R950= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- PTPRH | c.2175G>T p.R725= | Silent (SNP) | VAF 39/348 reads (11%) | catalogued as COSV54750318; called by muse, mutect2, varscan2
- QRSL1 | c.567A>T p.G189= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, varscan2
- RYR2 | c.3018G>T p.V1006= | Silent (SNP) | VAF 13/309 reads (4%) | called by muse, mutect2
- RYR3 | c.10857G>A p.R3619= (on ENST00000389232; = p.R3620= on NM_001036.6) | Silent (SNP) | VAF 30/424 reads (7%) | called by muse, mutect2
- SLC12A5 | c.105G>T p.P35= | Silent (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- SNX27 | c.1179C>T p.I393= | Silent (SNP) | VAF 28/214 reads (13%) | catalogued as rs1220663101; called by muse, mutect2
- SP5 | c.1011C>T p.F337= | Silent (SNP) | VAF 36/364 reads (10%) | called by muse, mutect2
- STOML1 | c.717C>G p.L239= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- TIAM1 | c.2949G>T p.G983= | Silent (SNP) | VAF 56/610 reads (9%) | called by muse, mutect2
- TMEM196 | c.294C>A p.S98= | Silent (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- TNRC18 | c.3717C>T p.C1239= | Silent (SNP) | VAF 36/220 reads (16%) | called by muse, mutect2, varscan2
- TYR | c.339A>T p.T113= | Silent (SNP) | VAF 59/581 reads (10%) | catalogued as COSV99634931; called by muse, mutect2, varscan2
- VPS13A | c.8208A>G p.T2736= | Silent (SNP) | VAF 95/580 reads (16%) | catalogued as rs1402671976; called by muse, mutect2, varscan2
- WDR83OS | c.147C>T p.L49= | Silent (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- ZNF385D | c.72C>A p.A24= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- ZNF653 | c.414G>A p.P138= | Silent (SNP) | VAF 34/448 reads (8%) | catalogued as rs201190251; called by muse, mutect2
- ZNF835 | c.1323G>T p.T441= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as COSV73379529; called by muse, mutect2, varscan2
- AC009053.1 | n.1041G>T | RNA (SNP) | VAF 47/418 reads (11%) | called by muse, mutect2, varscan2
- AC011410.1 | n.134C>A | RNA (SNP) | VAF 32/470 reads (7%) | catalogued as rs965022401; called by muse, mutect2
- AC024940.1 | n.4402G>T | RNA (SNP) | VAF 44/409 reads (11%) | called by muse, mutect2, varscan2
- ACTN2 | c.784-22G>T | Intron (SNP) | VAF 63/353 reads (18%) | called by muse, varscan2
- ADAM10 | c.207-16024C>A | Intron (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- ALDH7A1 | c.312+28C>G | Intron (SNP) | VAF 26/375 reads (7%) | called by muse, mutect2
- ANAPC15 | chr11:72107434 G>C | 3'Flank (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- ATRNL1 | c.-129C>A | 5'UTR (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38618G>T | Intron (SNP) | VAF 18/346 reads (5%) | catalogued as rs981845482; called by muse, mutect2
- C12orf54 | c.168+187A>T | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- CACNA1C | c.1481+564C>A | Intron (SNP) | VAF 26/380 reads (7%) | catalogued as rs746679026, COSV59695881; called by muse, mutect2
- CBFA2T3 | c.151+26078C>A | Intron (SNP) | VAF 103/628 reads (16%) | called by muse, varscan2
- CD7 | c.612+101C>T | Intron (SNP) | VAF 47/289 reads (16%) | catalogued as rs1020942578, COSV53939948; called by muse, mutect2, varscan2
- CHRNA4 | c.*927G>A | 3'UTR (SNP) | VAF 9/31 reads (29%) | called by mutect2, varscan2
- CREB5 | chr7:28409790 C>A | 5'Flank (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- CSMD3 | c.1030+60C>A | Intron (SNP) | VAF 32/197 reads (16%) | called by muse, mutect2
- DEFB121 | n.213G>A | RNA (SNP) | VAF 27/363 reads (7%) | catalogued as rs1393368087; called by muse, mutect2
- DGKI | c.2498-20T>A | Intron (SNP) | VAF 71/515 reads (14%) | called by muse, mutect2, varscan2
- DPF1 | c.676+374C>A | Intron (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- IGLV2-11 | c.-13G>A | 5'UTR (SNP) | VAF 32/284 reads (11%) | called by muse, varscan2
- MRPS2 | chr9:135500655 G>T | 5'Flank (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- MS4A4A | c.41+2014G>A | Intron (SNP) | VAF 11/74 reads (15%) | called by muse, varscan2
- MYADML | n.840C>A | RNA (SNP) | VAF 24/444 reads (5%) | called by muse, mutect2
- NAPRT | c.354+36_355-37del | Intron (DEL) | VAF 38/213 reads (18%) | called by mutect2, pindel, varscan2
- NCAM1 | c.1825+1140G>T | Intron (SNP) | VAF 28/550 reads (5%) | called by muse, mutect2
- NRK | c.-48T>A | 5'UTR (SNP) | VAF 35/202 reads (17%) | called by muse, mutect2, varscan2
- OR2L1P | n.936C>A | RNA (SNP) | VAF 84/412 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-66692G>T | Intron (SNP) | VAF 52/287 reads (18%) | catalogued as rs753384738, COSV52748838; called by muse, mutect2, varscan2
- POR | c.189-4143A>G | Intron (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- SIRPD | c.422-3011A>G | Intron (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- SLC7A13 | c.1180-1003C>T | Intron (SNP) | VAF 40/560 reads (7%) | called by muse, mutect2
- SPATA31C2 | n.2780C>A | RNA (SNP) | VAF 36/492 reads (7%) | called by muse, mutect2
- SYCE1 | chr10:133567850 G>T | 5'Flank (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- UMPS | c.*5067C>T | 3'UTR (SNP) | VAF 39/535 reads (7%) | called by muse, mutect2
- ZEB2 | chr2:144520272 G>T | 5'Flank (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- ZNF492 | c.-8G>T | 5'UTR (SNP) | VAF 42/752 reads (6%) | called by muse, mutect2
